TCGA case TCGA-H7-A76A — Head and Neck Squamous Cell Carcinoma (TCGA-HNSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Tonsil; Tissue source site: ABS - IUPUI. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/59a7d695-cb0c-47b8-ba9d-ca52ca2cfa7d

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 57 years; Vital status: Alive.

Diagnoses (1)
1. Squamous cell carcinoma, keratinizing, NOS: ICD-O-3 morphology code: 8071/3; ICD-10 code: C09.9; Tissue or organ of origin: Tonsil, NOS; Site of resection or biopsy: Head, face or neck, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 57.3 years (20,946 days); Year of diagnosis: 2013; AJCC staging edition: 7th; AJCC clinical T: T2; AJCC clinical N: N2b; AJCC clinical M: M0; AJCC clinical stage: Stage IVA; AJCC pathologic T: TX; AJCC pathologic N: N2b; AJCC pathologic M: MX; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Lymph node dissection site: Neck, NOS.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 2; Lymph nodes tested: 31; Lymphatic invasion present: Yes; Perineural invasion present: No; Vascular invasion present: Yes.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 62 days; Days to treatment end: 101 days; Treatment dose: 60 Gy; Treatment outcome: Complete Response; Treatment anatomic sites: Regional Site.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 62 days; Days to treatment end: 101 days; Treatment dose: 63 Gy; Treatment outcome: Complete Response; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 62 days; Days to treatment end: 101 days; Treatment outcome: Complete Response; Treatment anatomic sites: Regional Site.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Cure; Days to treatment end: 101 days; Treatment outcome: No Measurable Disease.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 206 days; Disease response: Tumor Free.
- Days to follow up: 637 days (1.7 years); Disease response: Tumor Free.

Molecular and laboratory tests
- CDKN2A: Positive.

Exposures
- Alcohol history: Yes; Alcohol drinks per day: 2; Alcohol days per week: 5.
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Tobacco smoking onset year: 1989; Tobacco smoking quit year: 1993.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-H7-A76A-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Initial weight: 510 mg.
  Slide TCGA-H7-A76A-01A-04-TS4: Section location: Top; Percent tumor cells: 20; Percent tumor nuclei: 40; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 70; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide TCGA-H7-A76A-01A-05-TS5: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 40; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-H7-A76A-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-H7-A76A-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Head and Neck; Histologic diagnosis: Head & Neck Squamous Cell Carcinoma; Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: Tumor free; Lymph nodes examined: Yes; Lymph node neck dissection indicator: Yes; Lymphovascular invasion: Yes; Tobacco smoking history indicator: 4; Alcohol consumption frequency: 5; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response; Definitive treatment method: Radiation; Definitive treatment evidence disease after: No; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 637 days; disease-specific survival: no event (censored), 637 days; progression-free interval: no event (censored), 637 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-H7-A76A-01A-51D-A34I-01): tumor purity 0.29, ploidy 2.14, whole-genome doublings 0.
